Somatic mutation profile of tumor specimen HCM-CSHL-0467-C56-06A (aliquot HCM-CSHL-0467-C56-06A-11D-A881-36) from HCMI case HCM-CSHL-0467-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IIIC; FIGO stage: Stage III; Tumor grade: High Grade.
Specimen HCM-CSHL-0467-C56-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f67a017-ec49-444a-8364-a6f30d6ee4d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0467-C56-10A (Blood Derived Normal), aliquot HCM-CSHL-0467-C56-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7aa9bdd-313e-46be-bb54-9fd2a429813a

The open-access MAF lists 105 somatic variants for this specimen: 83 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 19, Nonsense Mutation 6, 3'Flank 1, 5'UTR 1, In Frame Ins 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 151/184 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD31 | c.4066G>T p.D1356Y | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57156524; called by muse, mutect2, varscan2
- BRSK1 | c.1577C>T p.A526V | Missense Mutation (SNP) | VAF 110/476 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs777359528; called by muse, mutect2, varscan2
- CAPN15 | c.3041G>A p.R1014H | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781265101; called by muse, mutect2
- CDKN2A | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 224/570 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as rs1190283873, CM097979; called by muse, mutect2, varscan2
- CPZ | c.1849G>A p.D617N (on ENST00000360986 / NM_001014447.3; = p.D606N on NM_003652.3) | Missense Mutation (SNP) | VAF 185/437 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as rs760245531, COSV59923902; called by muse, mutect2, varscan2
- DNAH1 | c.2942G>A p.R981H | Missense Mutation (SNP) | VAF 131/657 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs374856706; called by muse, mutect2, varscan2
- EPS8L3 | c.1729C>T p.R577* (on ENST00000361965 / NM_133181.4; = p.R547* on NM_024526.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 139/511 reads (27%) | catalogued as rs147585592; called by muse, mutect2, varscan2
- FUT9 | c.139G>C p.V47L | Missense Mutation (SNP) | VAF 102/520 reads (20%) | SIFT tolerated (0.95); PolyPhen benign (0.02); catalogued as rs1412403248; called by muse, mutect2, varscan2
- HK2 | c.2546G>A p.R849H | Missense Mutation (SNP) | VAF 212/475 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs760432076; called by muse, mutect2, varscan2
- HYPK | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 81/388 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202106711, COSV51038302; called by muse, mutect2, varscan2
- ICAM4 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 135/307 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53425967; called by muse, mutect2, varscan2
- IER5 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 188/582 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1445529006; called by muse, varscan2
- INO80D | c.1045C>T p.R349W | Missense Mutation (SNP) | VAF 88/372 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs766341670; called by muse, mutect2, varscan2
- KCTD11 | c.263G>A p.R88H (on ENST00000333751 / NM_001363642.1; = p.R49H on NM_001002914.2) | Missense Mutation (SNP) | VAF 185/443 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV50135132; called by muse, mutect2, varscan2
- LRP2 | c.9127C>T p.R3043C | Missense Mutation (SNP) | VAF 422/517 reads (82%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as rs760320712, COSV55560197; called by muse, mutect2, varscan2
- LRP2 | c.5668C>A p.Q1890K | Missense Mutation (SNP) | VAF 77/339 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.254); catalogued as COSV99790173; called by muse, mutect2, varscan2
- LRP2 | c.4765C>T p.R1589C | Missense Mutation (SNP) | VAF 22/560 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs879176581, COSV55567293; called by muse, mutect2
- MYH7B | c.3464A>T p.K1155M | Missense Mutation (SNP) | VAF 98/488 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as rs201622278; called by muse, mutect2, varscan2
- OLFM1 | c.193C>G p.R65G | Missense Mutation (SNP) | VAF 122/284 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.3); catalogued as rs1372384625; called by muse, mutect2, varscan2
- PARD3B | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 36/483 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.022); catalogued as rs368769074; called by muse, mutect2
- PCDHB15 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 121/483 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.086); catalogued as COSV50858314; called by muse, mutect2, varscan2
- PCYT1A | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 109/605 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs867290911, COSV53057919; called by muse, mutect2, varscan2
- PNMA8A | c.486C>G p.F162L | Missense Mutation (SNP) | VAF 124/499 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV58138430; called by muse, mutect2, varscan2
- PNPLA6 | c.875C>T p.T292M (on ENST00000414982 / NM_001166111.2; = p.T244M on NM_006702.5) | Missense Mutation (SNP) | VAF 46/515 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772665971; called by muse, mutect2
- PNPLA6 | c.2773C>T p.R925C (on ENST00000414982 / NM_001166111.2; = p.R877C on NM_006702.5) | Missense Mutation (SNP) | VAF 199/486 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs377171140; called by muse, mutect2, varscan2
- RARS2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 31/628 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs201899366, COSV57638114, COSV57641021; called by muse, mutect2
- RASGEF1B | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 16/287 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV100021240, COSV52340132; called by muse, mutect2
- RCHY1 | c.195_196del p.C65* | Nonsense Mutation (DEL) | VAF 49/148 reads (33%) | catalogued as rs778879251; called by pindel, varscan2
- RNF139 | c.1760A>T p.Q587L | Missense Mutation (SNP) | VAF 117/267 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.818); catalogued as COSV104372530; called by muse, mutect2, varscan2
- RTL1 | c.3653G>A p.R1218H | Missense Mutation (SNP) | VAF 135/527 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as rs747974765; called by muse, mutect2, varscan2
- SEMA3D | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 52/250 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1562816970, COSV52388637; called by muse, mutect2, varscan2
- SLC46A3 | c.810T>A p.Y270* | Nonsense Mutation (SNP) | VAF 68/197 reads (35%) | catalogued as rs768643720, COSV57180202; called by muse, mutect2, varscan2
- SLC8B1 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 155/637 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs538747610, COSV99176662; called by muse, mutect2, varscan2
- SNX7 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 67/250 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1431330339, COSV60269239; called by muse, mutect2, varscan2
- TAX1BP3 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 128/315 reads (41%) | catalogued as rs749730290; called by muse, mutect2, varscan2
- TIMM44 | c.427C>G p.R143G | Missense Mutation (SNP) | VAF 106/324 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV54493528, COSV99564009; called by muse, mutect2, varscan2
- TMEM248 | c.711G>T p.W237C | Missense Mutation (SNP) | VAF 36/582 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs370465134; called by muse, mutect2
- ZIC5 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 376/653 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as rs913816048; called by muse, mutect2, varscan2
- ACBD3 | c.1547G>T p.R516L | Missense Mutation (SNP) | VAF 65/307 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKRD37 | c.18C>A p.C6* | Nonsense Mutation (SNP) | VAF 118/320 reads (37%) | called by muse, mutect2, varscan2
- ARHGAP21 | c.2249C>G p.P750R | Missense Mutation (SNP) | VAF 110/316 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF28 | c.2679T>G p.I893M | Missense Mutation (SNP) | VAF 13/473 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- AURKA | c.775C>A p.P259T | Missense Mutation (SNP) | VAF 700/1232 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA2D2 | c.3129C>A p.H1043Q (on ENST00000479441 / NM_001174051.3; = p.H1036Q on NM_006030.4) | Missense Mutation (SNP) | VAF 58/380 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CDH26 | c.458T>G p.I153S | Missense Mutation (SNP) | VAF 108/785 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CMBL | c.272G>C p.W91S | Missense Mutation (SNP) | VAF 89/300 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- CPT1B | c.442T>G p.L148V | Missense Mutation (SNP) | VAF 74/227 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP46A1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 88/316 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- DEAF1 | c.1426C>T p.Q476* | Nonsense Mutation (SNP) | VAF 117/377 reads (31%) | called by muse, mutect2, varscan2
- DTX1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 102/425 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- ECHDC1 | c.643G>A p.A215T (on ENST00000531967 / NM_001139510.1; = p.A209T on NM_001002030.2) | Missense Mutation (SNP) | VAF 147/374 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- ELOVL4 | c.479A>G p.Y160C | Missense Mutation (SNP) | VAF 154/385 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EYS | c.7037A>C p.N2346T | Missense Mutation (SNP) | VAF 18/408 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- KIAA0895L | c.1252G>C p.V418L | Missense Mutation (SNP) | VAF 68/209 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- KNL1 | c.1985A>G p.D662G (on ENST00000346991 / NM_170589.5; = p.D636G on NM_144508.5) | Missense Mutation (SNP) | VAF 32/426 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.125); called by muse, mutect2
- LINGO2 | c.721A>T p.M241L | Missense Mutation (SNP) | VAF 133/346 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC24 | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 119/312 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAF | c.703G>T p.G235C | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- MAP3K6 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 180/599 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MEPCE | c.249G>T p.Q83H | Missense Mutation (SNP) | VAF 186/596 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.044); called by muse, varscan2
- METTL11B | c.601C>A p.L201I | Missense Mutation (SNP) | VAF 59/242 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC17 | c.3699T>G p.S1233R | Missense Mutation (SNP) | VAF 118/422 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- MYO5A | c.4796G>A p.R1599Q | Missense Mutation (SNP) | VAF 133/477 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- OR51A4 | c.628G>C p.V210L | Missense Mutation (SNP) | VAF 14/410 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- OTOGL | c.1292T>C p.V431A (on ENST00000547103; = p.V422A on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/308 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PAGR1 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 112/493 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCNX2 | c.5297A>C p.H1766P | Missense Mutation (SNP) | VAF 14/456 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2
- POLR2B | c.888G>T p.E296D | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.308); called by muse, mutect2
- PRR27 | c.17G>C p.W6S | Missense Mutation (SNP) | VAF 84/221 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRRC2C | c.8320G>C p.E2774Q (on ENST00000367742; = p.E2772Q on NM_015172.4) | Missense Mutation (SNP) | VAF 157/551 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- PRX | c.1957C>T p.H653Y | Missense Mutation (SNP) | VAF 139/753 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- PSMC2 | c.818T>G p.F273C | Missense Mutation (SNP) | VAF 193/344 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBM39 | c.1508C>G p.A503G (on ENST00000253363 / NM_001323424.2; = p.A497G on NM_004902.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- RSRC1 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 98/276 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCIN | c.1301G>A p.G434E (on ENST00000297029 / NM_001112706.3; = p.G187E on NM_033128.3) | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SHH | c.64C>A p.L22M | Missense Mutation (SNP) | VAF 88/518 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- SHISA2 | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 20/384 reads (5%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.991); called by muse, mutect2
- SLC25A38 | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 56/544 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TMED6 | c.538_559del p.Y180Kfs*15 | Frame Shift Del (DEL) | VAF 41/208 reads (20%) | called by mutect2, pindel, varscan2
- TXK | c.585_587dup p.T196dup | In Frame Ins (INS) | VAF 85/190 reads (45%) | called by mutect2, pindel, varscan2
- WWC1 | c.2768C>A p.T923N | Missense Mutation (SNP) | VAF 121/757 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- XPO1 | c.1166C>G p.S389C | Missense Mutation (SNP) | VAF 81/769 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ADAMTS13 | c.4041C>T p.G1347= | Silent (SNP) | VAF 13/347 reads (4%) | catalogued as rs782321856, COSV52471453; called by muse, mutect2
- ANKRD36C | c.201C>T p.T67= | Silent (SNP) | VAF 14/165 reads (8%) | catalogued as rs942548316; called by muse, mutect2, varscan2
- CRHR1 | c.90C>T p.C30= | Silent (SNP) | VAF 111/501 reads (22%) | catalogued as rs543785844, COSV53278342; called by muse, mutect2, varscan2
- FAAH | c.1137G>A p.G379= | Silent (SNP) | VAF 98/332 reads (30%) | called by muse, mutect2, varscan2
- FBXO45 | c.105C>T p.A35= | Silent (SNP) | VAF 153/612 reads (25%) | called by muse, mutect2, varscan2
- FNDC1 | c.1263G>C p.L421= | Silent (SNP) | VAF 125/558 reads (22%) | called by muse, mutect2, varscan2
- FPGT | c.1374T>A p.A458= | Silent (SNP) | VAF 82/337 reads (24%) | called by muse, mutect2, varscan2
- HNF4G | c.804C>T p.I268= (on ENST00000354370 / NM_001330561.2; = p.I315= on NM_004133.5) | Silent (SNP) | VAF 104/347 reads (30%) | catalogued as rs748968405, COSV62966170, COSV62973661; called by muse, mutect2, varscan2
- KCNH7 | c.2010C>T p.Y670= | Silent (SNP) | VAF 125/447 reads (28%) | catalogued as rs891069994, COSV59789745; called by muse, mutect2, varscan2
- MED15 | c.2145C>T p.L715= (on ENST00000263205 / NM_001003891.3; = p.L675= on NM_015889.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 152/186 reads (82%) | called by muse, mutect2, varscan2
- NUF2 | c.1164T>C p.Y388= | Silent (SNP) | VAF 74/274 reads (27%) | called by mutect2, varscan2
- OGFOD3 | c.717C>T p.F239= | Silent (SNP) | VAF 176/344 reads (51%) | catalogued as rs950740124; called by muse, mutect2, varscan2
- OR10J5 | c.252C>T p.S84= | Silent (SNP) | VAF 74/345 reads (21%) | catalogued as rs897293838, COSV100604864; called by muse, mutect2, varscan2
- PKN1 | c.120G>A p.E40= | Silent (SNP) | VAF 157/1118 reads (14%) | called by muse, mutect2, varscan2
- PLBD1 | c.111T>C p.P37= | Silent (SNP) | VAF 74/329 reads (22%) | called by muse, varscan2
- SLC28A1 | c.600C>T p.C200= | Silent (SNP) | VAF 75/290 reads (26%) | catalogued as rs771748099, COSV99722339; called by muse, mutect2, varscan2
- TOR3A | c.550C>T p.L184= | Silent (SNP) | VAF 16/530 reads (3%) | called by muse, mutect2
- ZNF467 | c.564C>T p.C188= | Silent (SNP) | VAF 66/861 reads (8%) | called by muse, mutect2
- ZNF544 | c.699C>T p.N233= | Silent (SNP) | VAF 51/312 reads (16%) | catalogued as rs769187951; called by muse, mutect2, varscan2
- KCNQ1 | c.1393+24759A>C | Intron (SNP) | VAF 168/295 reads (57%) | called by muse, mutect2, varscan2
- RGS8 | c.-134A>T | 5'UTR (SNP) | VAF 97/415 reads (23%) | called by muse, mutect2, varscan2
- SLC44A5 | chr1:75203740 G>C | 3'Flank (SNP) | VAF 73/291 reads (25%) | called by muse, mutect2, varscan2
